Somatic mutation profile of tumor specimen TCGA-AD-A5EK-01A (aliquot TCGA-AD-A5EK-01A-11D-A28G-10) from TCGA case TCGA-AD-A5EK, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 51.3 years (18,731 days).
Specimen TCGA-AD-A5EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e8e2c48-c57a-4b9d-8792-5a5861b3f496.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-A5EK-10A (Blood Derived Normal), aliquot TCGA-AD-A5EK-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58a77f64-d6d6-4eef-9dca-2ec2906c927c

The open-access MAF lists 106 somatic variants for this specimen: 63 protein-altering or splice-affecting, 32 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 32, Nonsense Mutation 4, 3'UTR 4, 5'Flank 3, 3'Flank 2, In Frame Del 1, RNA 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 61/108 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 54/77 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1210C>T p.R404* (on ENST00000272895 / NM_173076.3; = p.R86* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as rs1458824013, COSV55953887; called by muse, mutect2, varscan2
- ABO | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs781789696, COSV101505916; called by muse, mutect2, varscan2
- ACTR1B | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56705654; called by muse, mutect2, varscan2
- ADAMTS16 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 72/104 reads (69%) | catalogued as rs772469674, COSV56976104; called by muse, mutect2, varscan2
- ANXA11 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368132715; called by muse, mutect2, varscan2
- APC | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 122/138 reads (88%) | catalogued as COSV57322620, COSV57331090; called by muse, mutect2, varscan2
- ATP6V0D2 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV53414107; called by muse, mutect2, varscan2
- BASP1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758132970, COSV59469386; called by muse, varscan2
- C2orf16 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs781531966, COSV62678104; called by muse, mutect2, varscan2
- CACNA1H | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 84/99 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV61998446; called by muse, mutect2, varscan2
- CCL22 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs146388634; called by muse, mutect2, varscan2
- CILP2 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs372029398; called by muse, mutect2, varscan2
- CMYA5 | c.4996G>T p.D1666Y | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs1455989325, COSV101484154, COSV71409626; called by muse, mutect2, varscan2
- COL4A1 | c.4006G>A p.V1336I | Missense Mutation (SNP) | VAF 78/251 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs202209298; called by muse, mutect2, varscan2
- COL4A4 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as rs886055726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRACDL | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 71/114 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0.178); catalogued as rs1281745322, COSV67410237; called by muse, mutect2, varscan2
- CUBN | c.8663C>T p.P2888L | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs777195712, COSV100913119, COSV64722388; called by muse, mutect2, varscan2
- DSCAM | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs756989790, COSV68022613; called by muse, mutect2, varscan2
- EIF2AK2 | c.1074G>C p.K358N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as COSV51796160; called by muse, mutect2, varscan2
- IL16 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746485239, COSV57263942; called by muse, mutect2, varscan2
- INHBA | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748226962; called by muse, mutect2, varscan2
- KCNA1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV66838347; called by muse, mutect2, varscan2
- KCNA5 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99364238; called by muse, mutect2, varscan2
- KDM4B | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs771331474, COSV50265931; called by muse, mutect2, varscan2
- KRT27 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56973519; called by muse, mutect2, varscan2
- LRP1B | c.12250C>T p.R4084C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1324319125, COSV67205670, COSV67248198; called by muse, mutect2, varscan2
- MAP3K1 | c.3857_3859del p.E1286del | In Frame Del (DEL) | VAF 94/186 reads (51%) | catalogued as rs1397309724; called by pindel, varscan2
- MUC5B | c.4267C>T p.R1423W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773760344, COSV71595671; called by muse, mutect2, varscan2
- NOS1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1450500022, COSV57607185; called by muse, mutect2, varscan2
- NR4A1 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV54480983; called by muse, mutect2, varscan2
- NRXN1 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58452844; called by muse, mutect2, varscan2
- NTRK3 | c.492C>A p.C164* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV58115663; called by muse, mutect2, varscan2
- OR2A12 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as rs202101971, COSV68821009; called by muse, mutect2, varscan2
- OR4D1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as rs563842371, COSV52125703; called by muse, mutect2, varscan2
- PBX4 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs550438529; called by muse, mutect2, varscan2
- PCDH8 | c.3097C>A p.L1033I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV58815372; called by muse, mutect2, varscan2
- PHKB | c.1715C>A p.T572N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54534630; called by muse, mutect2, varscan2
- PLPPR4 | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64567295; called by muse, mutect2, varscan2
- PRAMEF1 | c.1127G>T p.C376F | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100179335; called by muse, mutect2, varscan2
- RAB6B | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53315712; called by muse, mutect2, varscan2
- SPTBN4 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.462); catalogued as rs771682932; called by muse, mutect2, varscan2
- SSTR4 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs374915518; called by muse, mutect2, varscan2
- TCF20 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs765913677; called by muse, mutect2, varscan2
- ATP10D | c.1958C>A p.P653Q | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- C19orf71 | c.41_42insATCGGGGACC p.E19Gfs*15 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel*
- CARD11 | c.2557G>C p.G853R | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CYP7B1 | c.1502G>C p.R501T | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- DES | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EVC2 | c.2161C>A p.L721M | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LONRF2 | c.1510C>A p.L504M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAST4 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NR1I2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OGDH | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCM1 | c.3938A>C p.N1313T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PHC2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRDM9 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- RETREG1 | c.1031C>T p.S344F (on ENST00000306320 / NM_001034850.2; = p.S203F on NM_019000.4) | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- REXO4 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SPTBN4 | c.6388G>A p.G2130R | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TRIM22 | c.1022C>A p.A341D | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UFC1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 69/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM7 | c.1071C>T p.C357= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs762131594, COSV51534481; called by muse, mutect2, varscan2
- APOBEC3C | c.351C>T p.T117= | Silent (SNP) | VAF 76/186 reads (41%) | called by muse, mutect2, varscan2
- AQP11 | c.666G>A p.S222= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs752747579, COSV57993246; called by muse, mutect2, varscan2
- ATP10A | c.639C>T p.R213= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs954775189, COSV63515222; called by muse, mutect2, varscan2
- BSCL2 | c.1002C>T p.P334= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1233494509, COSV54017872; called by muse, mutect2, varscan2
- CCDC80 | c.612C>T p.T204= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV99244373; called by muse, mutect2, varscan2
- CCP110 | c.1629G>A p.K543= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs530011102; called by muse, mutect2, varscan2
- CLCN5 | c.2064C>T p.F688= | Silent (SNP) | VAF 141/161 reads (88%) | called by muse, mutect2, varscan2
- CYP4A22 | c.951G>A p.T317= | Silent (SNP) | VAF 72/477 reads (15%) | catalogued as rs201355991, COSV99594518; called by muse, mutect2, varscan2
- DCN | c.555G>A p.P185= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs147765043; called by muse, mutect2, varscan2
- DYNC2H1 | c.11709T>C p.I3903= | Silent (SNP) | VAF 32/71 reads (45%) | called by muse, varscan2
- FAM78A | c.375C>T p.S125= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs781391622, COSV55993156; called by muse, mutect2, varscan2
- GRM1 | c.2868C>T p.N956= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV51125608; called by muse, mutect2, varscan2
- HADHA | c.987G>A p.E329= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs1304444307, COSV66108675; called by muse, mutect2, varscan2
- IGSF1 | c.3999C>T p.P1333= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs770281870, COSV63835845; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1461C>T p.F487= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs768493681, COSV61148434; called by muse, mutect2, varscan2
- IVL | c.1119G>A p.L373= | Silent (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2, varscan2
- KDM4B | c.2820C>T p.I940= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs747587630, COSV50266165; ClinVar: likely benign; called by muse, mutect2, varscan2
- LDLR | c.2217G>A p.Q739= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- LETM2 | c.1194G>T p.P398= (on ENST00000379957 / NM_001286819.2; = p.P303= on NM_144652.3) | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV52686350; called by muse, mutect2, varscan2
- PCDHB9 | c.1710G>A p.A570= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs782654537; called by muse, mutect2, varscan2
- PNPLA7 | c.582C>T p.I194= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- SMC1A | c.1944G>A p.K648= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- SSTR3 | c.594G>A p.P198= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs776297016; called by muse, mutect2, varscan2
- TTBK1 | c.1401G>A p.G467= | Silent (SNP) | VAF 98/258 reads (38%) | catalogued as COSV52496788; called by muse, mutect2, varscan2
- TTLL9 | c.1254C>T p.N418= | Silent (SNP) | VAF 84/111 reads (76%) | catalogued as rs1230173477, COSV52431219; called by muse, mutect2, varscan2
- UNC93B1 | c.951C>T p.I317= | Silent (SNP) | VAF 47/114 reads (41%) | catalogued as rs1339505284; called by muse, mutect2, varscan2
- VWF | c.5541C>T p.N1847= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs146540001; called by muse, mutect2, varscan2
- WASHC4 | c.348C>G p.L116= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as rs1409843763; called by muse, mutect2, varscan2
- XKR6 | c.1371G>A p.T457= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs750390583; called by muse, mutect2, varscan2
- ZNF35 | c.1551C>T p.L517= | Silent (SNP) | VAF 107/235 reads (46%) | called by muse, mutect2, varscan2
- ZNF532 | c.573G>A p.T191= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as rs371823083, COSV60172659; called by muse, mutect2, varscan2
- AC073254.1 | chr2:232581006 G>A | 3'Flank (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.1043-14C>T | Intron (SNP) | VAF 59/154 reads (38%) | catalogued as rs531690505; called by muse, mutect2, varscan2
- C6orf120 | c.*436C>A | 3'UTR (SNP) | VAF 49/94 reads (52%) | catalogued as COSV100179029; called by muse, mutect2, varscan2
- CHODL | c.*57A>G | 3'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- KCNA6 | chr12:4814390 C>T | 3'Flank (SNP) | VAF 35/81 reads (43%) | catalogued as rs897290319, COSV99768208; called by muse, mutect2, varscan2
- LILRB4 | chr19:54662950 C>T | 5'Flank (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99553391; called by muse, mutect2, varscan2
- NPAP1 | c.*2616G>T | 3'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as rs1401623838, COSV100274570; called by muse, varscan2
- PCDHB7 | c.*861C>A | 3'UTR (SNP) | VAF 30/116 reads (26%) | catalogued as COSV99175195; called by muse, mutect2, varscan2
- RPS17P5 | n.9C>A | RNA (SNP) | VAF 64/176 reads (36%) | called by muse, mutect2, varscan2
- S1PR3 | chr9:88991142 G>A | 5'Flank (SNP) | VAF 66/106 reads (62%) | catalogued as COSV57837450; called by muse, mutect2, varscan2
- TFAP2A | chr6:10419455 G>A | 5'Flank (SNP) | VAF 136/329 reads (41%) | catalogued as COSV100116430; called by muse, mutect2, varscan2
